Somatic mutation profile of tumor specimen TCGA-KQ-A41P-01A (aliquot TCGA-KQ-A41P-01A-12D-A339-08) from TCGA case TCGA-KQ-A41P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,816 days).
Specimen TCGA-KQ-A41P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c3167f4-7dac-47f3-abdb-c4ce6e33da97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KQ-A41P-10F (Blood Derived Normal), aliquot TCGA-KQ-A41P-10F-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33037ecd-8abf-48e0-9942-9b91e425d762

The open-access MAF lists 351 somatic variants for this specimen: 255 protein-altering or splice-affecting, 89 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 212, Silent 89, Nonsense Mutation 28, Splice Region 4, Splice Site 4, Intron 2, Translation Start Site 2, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.4297C>T p.Q1433* | Nonsense Mutation (SNP) | VAF 32/37 reads (86%) | catalogued as rs797045278, COSV99271215; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>C p.R280T | Missense Mutation (SNP) | VAF 39/46 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1552C>T p.H518Y | Missense Mutation (SNP) | VAF 56/64 reads (88%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs573836993, COSV63972470; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ADGRL3 | c.3393C>T p.I1131= (on ENST00000506720 / NM_001322402.2; = p.I1063= on NM_015236.6) | Splice Region (SNP) | VAF 5/28 reads (18%) | catalogued as rs1345886810, COSV72231224; called by muse, mutect2, varscan2
- ADGRV1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.075); catalogued as rs1291844561, COSV101315737, COSV101316345; called by muse, mutect2
- ALAS1 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV59628412, COSV59628708; called by muse, mutect2, varscan2
- ANGPT4 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67922237; called by muse, mutect2, varscan2
- ARFGEF3 | c.6193C>T p.Q2065* | Nonsense Mutation (SNP) | VAF 9/10 reads (90%) | catalogued as COSV99294451; called by muse, mutect2, varscan2
- ARID2 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100537157, COSV57609310; called by muse, mutect2, varscan2
- ATP4A | c.1253C>T p.S418L | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV52869615; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 122/211 reads (58%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.819); catalogued as rs1184527849, COSV52875414; called by muse, mutect2, varscan2
- AVL9 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV59467297; called by muse, mutect2
- BOC | c.3005C>T p.T1002I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV56354512; called by muse, mutect2, varscan2
- BPTF | c.3344C>T p.S1115L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58841463, COSV58845092; called by muse, mutect2, varscan2
- BRD2 | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV66373957; called by muse, mutect2, varscan2
- BRDT | c.1506A>T p.E502D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV62865966; called by muse, mutect2, varscan2
- BRINP1 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56306132; called by muse, mutect2, varscan2
- BRWD3 | c.4696G>C p.E1566Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.188); catalogued as rs772657050, COSV64751010; called by muse, mutect2, varscan2
- C6orf120 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59323232; called by muse, mutect2, varscan2
- CACNB2 | c.194C>T p.S65L (on ENST00000324631 / NM_201596.3; = p.S37L on NM_201571.4) | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV56635779, COSV99996190; called by muse, mutect2
- CARM1 | c.1560G>C p.L520F | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53404389; called by muse, mutect2, varscan2
- CATSPERG | c.1473C>G p.I491M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53050902; called by muse, mutect2, varscan2
- CCDC110 | c.2084C>G p.S695* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1449363881, COSV100294121; called by muse, mutect2, varscan2
- CCDC110 | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV56872301; called by muse, mutect2, varscan2
- CCDC39 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 17/65 reads (26%) | catalogued as COSV99870281; called by muse, mutect2
- CCDC47 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV56723765; called by muse, mutect2, varscan2
- CCDC65 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV56739835; called by muse, mutect2, varscan2
- CCKAR | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.696); catalogued as COSV55162549; called by muse, mutect2, varscan2
- CCN6 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 93/107 reads (87%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV57889806; called by muse, mutect2, varscan2
- CD300E | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV60791061; called by muse, mutect2, varscan2
- CDH5 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV58518660; called by muse, mutect2
- CDK11A | c.1783G>C p.E595Q (on ENST00000378633 / NM_001313896.2; = p.E592Q on NM_024011.4) | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52307451; called by muse, mutect2
- CEP104 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764238062, COSV65512538; called by muse, mutect2, varscan2
- CFAP44 | c.2246C>G p.S749C | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV55608654, COSV55613523; called by muse, mutect2, varscan2
- CFAP69 | c.565C>G p.Q189E | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV60186888; called by muse, mutect2, varscan2
- CHD6 | c.7181G>C p.G2394A | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV64692598; called by muse, mutect2, varscan2
- CHMP4B | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | catalogued as COSV54137676, COSV99459985; called by muse, mutect2, varscan2
- CIP2A | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55420006; called by muse, mutect2, varscan2
- CLASP1 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV55330353; called by muse, mutect2, varscan2
- COL13A1 | c.958C>T p.R320W (on ENST00000398978 / NM_001130103.2; = p.R263W on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs985888177, COSV62572064; called by muse, mutect2, varscan2
- COL17A1 | c.3037G>C p.E1013Q | Missense Mutation (SNP) | VAF 141/218 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV62228050; called by muse, mutect2, varscan2
- COLGALT1 | c.432G>C p.M144I | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.733); catalogued as COSV53110331; called by muse, mutect2, varscan2
- COPA | c.2227T>C p.S743P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54105661; called by muse, mutect2
- COX7B2 | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as COSV57213754, COSV57219405; called by muse, mutect2, varscan2
- CRABP2 | c.326C>G p.S109W | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.872); catalogued as COSV63959032, COSV63959081; called by muse, mutect2
- CRMP1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.193); catalogued as COSV61481494; called by muse, mutect2, varscan2
- CSNK1A1 | c.867C>G p.N289K | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV55796467; called by muse, mutect2, varscan2
- CT45A1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.092); catalogued as rs782135417; called by muse, mutect2, varscan2
- CTNNA3 | c.1789T>A p.S597T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65567456, COSV65602319; called by muse, mutect2, varscan2
- CUL3 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52366295, COSV52371086; called by muse, mutect2, varscan2
- CUX1 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.448); catalogued as rs1554518585, COSV52906255; called by muse, mutect2, varscan2
- CYP2D6 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs377488485; called by muse, mutect2, varscan2
- CYP4X1 | c.1453C>G p.L485V | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as COSV64151230; called by muse, mutect2, varscan2
- DDX19B | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99850148; called by muse, mutect2, varscan2
- DEFB121 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as COSV66236533; called by muse, mutect2, varscan2
- DENND5A | c.2968C>T p.Q990* | Nonsense Mutation (SNP) | VAF 61/172 reads (35%) | catalogued as rs1554910362, COSV100065115; called by muse, varscan2
- DEPDC5 | c.3224C>G p.S1075C (on ENST00000400246; = p.S1144C on NM_014662.5) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV56690830; called by muse, mutect2, varscan2
- DGAT2L6 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.499); catalogued as COSV100284113; called by muse, mutect2, varscan2
- DGKD | c.2749G>A p.D917N (on ENST00000264057 / NM_152879.3; = p.D873N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51068425; called by muse, mutect2, varscan2
- DKK2 | c.77C>G p.S26* | Nonsense Mutation (SNP) | VAF 89/157 reads (57%) | catalogued as COSV99569347; called by muse, mutect2, varscan2
- DMTF1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.55); catalogued as COSV58686815; called by muse, mutect2, varscan2
- DNAH11 | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1235356652, COSV60951457; called by muse, mutect2, varscan2
- DNAH9 | c.8705C>T p.S2902F | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52360613; called by muse, mutect2, varscan2
- DNHD1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 75/135 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761369523, COSV54439694; called by muse, mutect2, varscan2
- DPPA3 | c.410T>A p.V137E | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV61503259; called by muse, mutect2, varscan2
- DTNA | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV52013495; called by muse, mutect2, varscan2
- EIF3E | c.1118A>C p.N373T | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55204265; called by muse, mutect2, varscan2
- EIF3L | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67739835; called by muse, mutect2, varscan2
- EPS8 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV55533567; called by muse, mutect2, varscan2
- ETNK2 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV65819957; called by muse, mutect2, varscan2
- FHOD3 | c.609C>T p.F203= | Splice Region (SNP) | VAF 3/13 reads (23%) | catalogued as COSV99942364; called by muse, mutect2
- FITM1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs759275530, COSV52823809, COSV52825607; called by muse, mutect2, varscan2
- FN3KRP | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs770978856, COSV53930344, COSV99485021; called by muse, mutect2, varscan2
- FREM2 | c.3655G>T p.D1219Y | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54843940; called by muse, varscan2
- FTL | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV53170999; called by muse, mutect2, varscan2
- GBP5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752091819, COSV58591216, COSV58593543; called by muse, mutect2, varscan2
- GBP6 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV65012005; called by muse, mutect2, varscan2
- GLTPD2 | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV58702772; called by muse, mutect2, varscan2
- GRIK2 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59752268; called by muse, mutect2, varscan2
- GRM1 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.873); catalogued as COSV51159383, COSV51197406; called by muse, mutect2, varscan2
- HAS1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs530794115, COSV55785948; called by muse, mutect2, varscan2
- HEPHL1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779368553, COSV59893961; called by muse, mutect2, varscan2
- HFM1 | c.376C>G p.Q126E | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.351); catalogued as COSV54032100; called by muse, mutect2, varscan2
- HIF1A | c.1387C>T p.R463* | Nonsense Mutation (SNP) | VAF 17/143 reads (12%) | catalogued as COSV60189949; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.226G>C p.D76H (on ENST00000354667 / NM_031243.3; = p.D64H on NM_002137.4) | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61160210, COSV61160744; called by muse, mutect2, varscan2
- HOXA11 | c.378C>G p.F126L | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV50052955, COSV50053869; called by muse, mutect2, varscan2
- HRC | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV53257519; called by muse, mutect2, varscan2
- IGF2BP3 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs1486180154, COSV51688741; called by muse, mutect2, varscan2
- IGLV1-44 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 150/288 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); catalogued as rs532762324; called by muse, varscan2
- ILF3 | c.2021G>A p.S674N | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51560031; called by muse, mutect2, varscan2
- INO80 | c.3787G>A p.E1263K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62740151; called by muse, mutect2, varscan2
- INTU | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV56540853; called by muse, mutect2, varscan2
- ITGA4 | c.1957A>G p.S653G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV67898114; called by muse, mutect2, varscan2
- ITK | c.1082C>G p.S361* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV101439855; called by muse, mutect2, varscan2
- KBTBD3 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.237); catalogued as COSV73241522; called by muse, mutect2, varscan2
- KCNA5 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV52907350; called by muse, mutect2, varscan2
- KCNS3 | c.1173C>G p.I391M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV58407967; called by muse, mutect2, varscan2
- KCNV1 | c.1026T>G p.C342W | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52087362; called by muse, mutect2, varscan2
- KDM5A | c.4751G>A p.R1584K | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV66994380; called by muse, mutect2
- KDM6A | c.2215_2216insC p.N739Tfs*11 | Frame Shift Ins (INS) | VAF 26/28 reads (93%) | catalogued as COSV65042902; called by mutect2, varscan2
- KIDINS220 | c.1322A>G p.D441G | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV56755946; called by muse, mutect2, varscan2
- KIF3B | c.289C>G p.Q97E | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65228365; called by muse, varscan2
- KIF3B | c.1074C>A p.F358L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV65228391; called by muse, mutect2, varscan2
- KIT | c.2003T>C p.V668A | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55410603; called by muse, mutect2, varscan2
- KLF6 | c.103-1G>C p.X35_splice | Splice Site (SNP) | VAF 26/42 reads (62%) | catalogued as COSV51495286; called by muse, mutect2, varscan2
- KLHDC7A | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.95); PolyPhen benign (0.048); catalogued as rs746757189, COSV68769178; called by muse, mutect2
- LAMC2 | c.1563C>A p.N521K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV51457628; called by muse, mutect2, varscan2
- LENEP | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.906); catalogued as COSV52698242; called by muse, mutect2, varscan2
- LILRB1 | c.794C>G p.S265* (on ENST00000427581; = p.S229* on NM_006669.6) | Nonsense Mutation (SNP) | VAF 69/137 reads (50%) | catalogued as COSV61119023; called by muse, mutect2, varscan2
- LIN7A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs779467317, COSV54018072; called by muse, mutect2, varscan2
- MAN1B1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as COSV65378261; called by muse, mutect2
- MAP3K8 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV99552285; called by muse, mutect2, varscan2
- MAPK3 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV53775016; called by muse, mutect2, varscan2
- MATR3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.027); catalogued as rs1190247069, COSV63078364; called by muse, mutect2, varscan2
- MCTP2 | c.1973C>G p.S658* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV59143342; called by muse, mutect2, varscan2
- MIA3 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 47/59 reads (80%) | catalogued as COSV100719521; called by muse, mutect2, varscan2
- MMAA | c.1205C>A p.S402Y | Missense Mutation (SNP) | VAF 36/310 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV55580945; called by muse, mutect2, varscan2
- MMP14 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.61); PolyPhen benign (0.163); catalogued as COSV61288869; called by muse, mutect2, varscan2
- MPHOSPH9 | c.2674G>C p.D892H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs775448176, COSV56621761; called by muse, mutect2, varscan2
- MPL | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | catalogued as rs763144679, CM010062, COSV65247904; called by muse, mutect2, varscan2
- MROH1 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1355363903; called by muse, mutect2, varscan2
- MROH2B | c.3919T>A p.L1307M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.739); catalogued as COSV68186745; called by muse, mutect2, varscan2
- MSLNL | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV99558596; called by muse, mutect2, varscan2
- MTPAP | c.151G>T p.E51* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as COSV99554264; called by muse, mutect2, varscan2
- MTR | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as rs1322149560, COSV63968800; called by muse, mutect2, varscan2
- MUC16 | c.21001C>T p.Q7001* | Nonsense Mutation (SNP) | VAF 106/197 reads (54%) | catalogued as COSV101201006; called by muse, mutect2, varscan2
- MYH3 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs777914421, COSV56867310; called by muse, mutect2, varscan2
- MYO5C | c.2656C>T p.Q886* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV99955262; called by muse, mutect2, varscan2
- NAA25 | c.2185_2215del p.L729Rfs*36 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | catalogued as COSV55706297; called by mutect2, pindel
- NBAS | c.4810G>A p.E1604K | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as COSV55729336; called by muse, mutect2, varscan2
- NCOA7 | c.2412G>C p.W804C | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57654342, COSV57657475; called by muse, mutect2, varscan2
- NFKB1 | c.2851C>G p.L951V (on ENST00000394820 / NM_001382627.1; = p.L952V on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56954557, COSV56958952; called by muse, mutect2, varscan2
- NIBAN1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV62286255; called by muse, mutect2, varscan2
- NLGN1 | c.194T>G p.I65S | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV64340282; called by muse, mutect2
- NOP56 | c.1353G>C p.K451N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1489525851, COSV100250089, COSV61390763; called by muse, mutect2, varscan2
- NUP153 | c.4235C>T p.S1412L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV50454688, COSV99468052; called by muse, mutect2, varscan2
- NUTF2 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54645735; called by muse, mutect2, varscan2
- OR10H1 | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1464239372, COSV58472307; called by muse, mutect2, varscan2
- OR51B2 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV60917153; called by muse, mutect2, varscan2
- OXCT1 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52173615; called by muse, mutect2, varscan2
- P3H2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752928706, COSV60024253; called by muse, mutect2, varscan2
- PADI4 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64924452; called by muse, mutect2, varscan2
- PCDHB1 | c.2249C>G p.S750C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as COSV60632012; called by muse, mutect2, varscan2
- PCNP | c.280-1G>C p.X94_splice | Splice Site (SNP) | VAF 29/61 reads (48%) | catalogued as COSV54576826; called by muse, mutect2, varscan2
- PCNT | c.5872C>T p.H1958Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV100855924; called by muse, varscan2
- PHF12 | c.334A>G p.K112E | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.043); catalogued as COSV52017843, COSV52020611; called by muse, mutect2, varscan2
- PI16 | c.702_704del p.S235del | In Frame Del (DEL) | VAF 30/57 reads (53%) | catalogued as rs747267930; called by pindel, varscan2
- PIP4K2A | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60541716; called by muse, varscan2
- PIP4K2A | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as COSV100114595, COSV60541724; called by muse, varscan2
- PKHD1 | c.3286C>A p.L1096I | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61885928; called by muse, mutect2, varscan2
- PLEC | c.3542C>T p.S1181F (on ENST00000322810 / NM_201380.4; = p.S1071F on NM_000445.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100517807; called by muse, mutect2, varscan2
- PLXDC2 | c.784-1G>C p.X262_splice | Splice Site (SNP) | VAF 14/54 reads (26%) | catalogued as COSV65906170; called by muse, mutect2, varscan2
- PNPT1 | c.2067C>T p.I689= | Splice Region (SNP) | VAF 5/56 reads (9%) | catalogued as COSV53178665; called by muse, mutect2, varscan2
- POLE | c.5994G>C p.M1998I | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV57685039; called by muse, mutect2, varscan2
- POU6F2 | c.1661G>A p.G554D | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV68877182; called by muse, mutect2
- PPIE | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.198); catalogued as COSV60972281; called by mutect2, varscan2
- PPP1R10 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); catalogued as COSV64739815; called by muse, mutect2, varscan2
- PPP1R16A | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV52953920; called by muse, mutect2
- PPP6R2 | c.273G>C p.Q91H | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as COSV53295795; called by muse, mutect2, varscan2
- PRKACA | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54115999; called by muse, mutect2, varscan2
- PRMT1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV101212323; called by muse, mutect2
- PRMT7 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59834304; called by muse, mutect2, varscan2
- PRPF6 | c.2475G>C p.Q825H | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV53874247; called by muse, mutect2, varscan2
- PTGS2 | c.1144C>G p.Q382E | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV66568686, COSV66570357; called by muse, mutect2, varscan2
- PTPRB | c.184C>G p.H62D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51738569; called by muse, mutect2, varscan2
- PYGO2 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV63757338; called by muse, mutect2, varscan2
- QPCTL | c.1087C>A p.P363T | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.918); catalogued as COSV50004282; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 21/95 reads (22%) | catalogued as COSV100228551, COSV56958719, COSV56963339; called by muse, mutect2, varscan2
- RAC2 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); catalogued as COSV50774799; called by muse, mutect2, varscan2
- RAD51D | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as COSV60005482; called by muse, mutect2, varscan2
- RAI1 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV55395493; called by muse, mutect2, varscan2
- RAI1 | c.4069C>G p.L1357V | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55391294, COSV55395511; called by muse, mutect2, varscan2
- RALGAPA2 | c.1292G>A p.R431K | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.45); PolyPhen benign (0.209); catalogued as COSV52503646; called by muse, mutect2, varscan2
- RB1CC1 | c.4326G>A p.M1442I | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV50257415; called by muse, mutect2, varscan2
- RELL2 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs750295136, COSV51837970; called by muse, mutect2, varscan2
- RIPK3 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53476368; called by muse, mutect2, varscan2
- RIPOR3 | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as rs751702128, COSV99246988; called by muse, mutect2, varscan2
- RNF213 | c.12353C>T p.S4118F | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511086, COSV60402913; called by muse, varscan2
- RNF220 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62405384; called by muse, mutect2, varscan2
- SAA1 | c.249C>G p.I83M | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV62946211, COSV62946470; called by muse, mutect2, varscan2
- SCLT1 | c.1814G>C p.R605T | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV55409293, COSV99827555; called by muse, mutect2, varscan2
- SCLT1 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs757265016, COSV55409307; called by muse, varscan2
- SDCBP | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.917); catalogued as rs1262066631, COSV50692635; called by muse, mutect2
- SDCBP2 | c.343G>A p.E115K (on ENST00000339987 / NM_001199784.1; = p.E30K on NM_015685.5) | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV100378346; called by muse, mutect2, varscan2
- SEC24B | c.2088G>C p.L696F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54502372; called by muse, mutect2, varscan2
- SHANK1 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs941454412, COSV53247657; called by muse, mutect2, varscan2
- SIGLEC1 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52467761; called by muse, mutect2, varscan2
- SLC13A1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52014017; called by muse, mutect2, varscan2
- SLC9C1 | c.1410G>C p.M470I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59890173; called by muse, mutect2, varscan2
- SUPT16H | c.484-1G>C p.X162_splice | Splice Site (SNP) | VAF 21/93 reads (23%) | catalogued as COSV53526260; called by muse, mutect2, varscan2
- SUPT3H | c.592G>A p.E198K (on ENST00000371460 / NM_181356.3; = p.E187K on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as COSV60944358; called by muse, mutect2, varscan2
- SYNE2 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs1165975231, COSV100648334, COSV59967526; called by muse, mutect2, varscan2
- SYNJ1 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470400490, COSV59151909; called by muse, mutect2, varscan2
- SYNPO2L | c.2353C>T p.R785W (on ENST00000394810 / NM_001114133.3; = p.R561W on NM_024875.5) | Missense Mutation (SNP) | VAF 76/121 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs77249183, COSV65739044; called by muse, mutect2, varscan2
- TAF1L | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as COSV99645247; called by muse, mutect2, varscan2
- TARS1 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV99466364; called by muse, mutect2
- TCF21 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 49/65 reads (75%) | SIFT tolerated (0.21); PolyPhen benign (0.129); catalogued as rs1243221906, COSV52818803; called by muse, mutect2, varscan2
- TET1 | c.1820C>G p.T607S | Missense Mutation (SNP) | VAF 44/70 reads (63%) | SIFT tolerated (0.42); PolyPhen benign (0.285); catalogued as COSV65386788; called by muse, mutect2, varscan2
- TEX2 | c.2320C>T p.L774F (on ENST00000583097 / NM_001288733.2; = p.L781F on NM_018469.5) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV51983303; called by muse, mutect2, varscan2
- TEX29 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs746032387, COSV52095937; called by muse, mutect2, varscan2
- TGM2 | c.806G>C p.C269S | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV63931918; called by muse, mutect2, varscan2
- TGM5 | c.984G>T p.K328N (on ENST00000220420 / NM_201631.4; = p.K246N on NM_004245.4) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.585); catalogued as COSV55010975; called by muse, mutect2, varscan2
- TH | c.1084G>C p.E362Q (on ENST00000381178 / NM_199292.3; = p.E331Q on NM_000360.4) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60767864; called by muse, mutect2, varscan2
- TIMM44 | c.1065C>G p.I355M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV54493017, COSV54494912; called by muse, mutect2, varscan2
- TLX3 | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as rs1561843258, COSV99740768; called by muse, mutect2
- TMEM132D | c.2103G>C p.Q701H | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.363); catalogued as COSV67161205; called by muse, mutect2, varscan2
- TMEM94 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.309); catalogued as COSV58597922; called by muse, mutect2, varscan2
- TMTC2 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58275761; called by muse, mutect2, varscan2
- TNPO3 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV55280979, COSV99603344; called by muse, mutect2, varscan2
- TNRC6B | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.318); catalogued as COSV57301300; called by muse, mutect2, varscan2
- TOM1L1 | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as COSV61948498; called by muse, mutect2, varscan2
- TOP1MT | c.1584G>T p.E528D | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV61318731; called by muse, varscan2
- TRHDE | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.242); catalogued as rs368667547, COSV53854060; called by muse, mutect2, varscan2
- TRIM36 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as COSV56691507; called by muse, mutect2, varscan2
- TRIO | c.2214C>T p.L738= | Splice Region (SNP) | VAF 28/70 reads (40%) | catalogued as COSV60088223; called by muse, mutect2, varscan2
- TRMT12 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 31/114 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60777446; called by muse, mutect2, varscan2
- TSC22D2 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62623005; called by muse, mutect2, varscan2
- TTF2 | c.346C>T p.H116Y | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV65633122; called by muse, mutect2, varscan2
- TTN | c.101143G>C p.E33715Q (on ENST00000591111; = p.E26291Q on NM_003319.4) | Missense Mutation (SNP) | VAF 56/67 reads (84%) | PolyPhen possibly damaging (0.479); catalogued as COSV59970809, COSV60186124, COSV60420754; called by muse, mutect2, varscan2
- TTN | c.37756T>G p.L12586V (on ENST00000591111; = p.L5162V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/124 reads (34%) | PolyPhen benign (0.007); catalogued as COSV60186145; called by muse, mutect2, varscan2
- UAP1 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1035407632, COSV54850616; called by muse, mutect2, varscan2
- UBA52 | c.282G>A p.M94I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV70615343, COSV70615452; called by muse, mutect2, varscan2
- UBE2D3 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.337); catalogued as COSV57661225; called by muse, mutect2, varscan2
- UFL1 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65149457, COSV65150206; called by muse, mutect2, varscan2
- USH2A | c.9328C>T p.P3110S | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56398888; called by muse, mutect2
- USP34 | c.3973C>T p.Q1325* | Nonsense Mutation (SNP) | VAF 48/212 reads (23%) | catalogued as COSV101277160; called by muse, mutect2, varscan2
- UTP3 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1289521356, COSV54661444; called by muse, mutect2, varscan2
- UTRN | c.6906G>T p.M2302I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62341006; called by muse, mutect2, varscan2
- VEGFB | c.527C>G p.A176G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV58537411; called by muse, mutect2, varscan2
- VIM | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56405296; called by muse, mutect2, varscan2
- VPS50 | c.1874T>A p.M625K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV58508943; called by muse, mutect2, varscan2
- VPS53 | c.34G>T p.E12* | Nonsense Mutation (SNP) | VAF 22/121 reads (18%) | catalogued as COSV99346557; called by muse, mutect2, varscan2
- WIF1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1303645603, COSV54133550; called by muse, mutect2, varscan2
- XIRP2 | c.4020A>C p.E1340D (on ENST00000628543; = p.E1515D on NM_152381.6) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54692891; called by muse, mutect2, varscan2
- XPC | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.275); catalogued as COSV53206244; called by muse, mutect2
- YBX2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs771681443, COSV50301571; called by muse, mutect2, varscan2
- ZBTB16 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV60096124; called by muse, mutect2, varscan2
- ZC3H13 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.247); catalogued as COSV54458691; called by muse, mutect2, varscan2
- ZDHHC23 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100362232; called by muse, mutect2, varscan2
- ZIK1 | c.467A>C p.K156T | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.617); catalogued as COSV56737773; called by muse, mutect2, varscan2
- ZMYM4 | c.2969T>G p.V990G | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58913818; called by muse, mutect2, varscan2
- ZNF224 | c.778T>A p.Y260N | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV61242816; called by muse, mutect2, varscan2
- ZNF292 | c.3491C>G p.S1164* | Nonsense Mutation (SNP) | VAF 22/27 reads (81%) | catalogued as COSV100370948; called by muse, mutect2, varscan2
- ZNF318 | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.242); catalogued as rs777987883, COSV58934671; called by muse, mutect2, varscan2
- ZNF345 | c.1358T>G p.L453R | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV59323011; called by muse, mutect2, varscan2
- ZNF382 | c.785T>G p.L262R | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as COSV53086947, COSV53090294; called by muse, mutect2, varscan2
- ZNF507 | c.218C>G p.S73* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV100322045; called by muse, mutect2, varscan2
- ZNF638 | c.4351G>A p.E1451K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52491494; called by muse, mutect2, varscan2
- ZNF746 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1227482488, COSV61408208; called by muse, mutect2, varscan2
- ZNF790 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 73/124 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV63212800; called by muse, mutect2, varscan2
- IGKV2D-28 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by mutect2, varscan2
- SOS2 | c.3227_3241delinsAA p.L1076Qfs*25 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | called by pindel, varscan2*
- TRPV1 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- WASHC2A | c.3755G>C p.R1252T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ZFP36L1 | c.584dup p.P196Sfs*6 | Frame Shift Ins (INS) | VAF 50/90 reads (56%) | called by mutect2, pindel, varscan2
- ABCA6 | c.2832C>A p.G944= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1214221188; called by muse, mutect2
- ABCG1 | c.840C>T p.L280= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV59207332; called by muse, mutect2, varscan2
- ADAMTS4 | c.588C>T p.V196= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV63488209; called by muse, mutect2
- AKAP17A | c.621C>T p.F207= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as COSV58310880; called by muse, mutect2, varscan2
- ARHGEF1 | c.1527G>A p.Q509= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV61528645; called by muse, mutect2
- ASB8 | c.537C>T p.V179= | Silent (SNP) | VAF 52/98 reads (53%) | catalogued as COSV56658996; called by muse, mutect2, varscan2
- ATAT1 | c.288C>T p.F96= | Silent (SNP) | VAF 111/143 reads (78%) | catalogued as COSV52542023; called by muse, mutect2, varscan2
- ATP2C2 | c.405C>T p.V135= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV52298441; called by muse, mutect2, varscan2
- ATP2C2 | c.2004C>T p.I668= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs543129889, COSV52298452; called by muse, mutect2, varscan2
- ATP5MC3 | c.195C>T p.I65= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV52976871; called by muse, mutect2, varscan2
- C3orf62 | c.135G>A p.Q45= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs753533071, COSV55538441; called by muse, mutect2, varscan2
- CACNA1D | c.2712C>T p.A904= (on ENST00000350061 / NM_001128840.3; = p.A924= on NM_000720.4) | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs148699423; ClinVar: likely benign; called by muse, mutect2, varscan2
- CARM1 | c.1650G>A p.R550= | Silent (SNP) | VAF 76/148 reads (51%) | catalogued as COSV53404395; called by muse, mutect2, varscan2
- CCDC80 | c.1575G>A p.Q525= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1214948179, COSV52818362; called by muse, mutect2, varscan2
- CHD2 | c.2904G>A p.L968= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV67711527; called by muse, mutect2, varscan2
- CLUL1 | c.231G>C p.L77= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as COSV58112736; called by muse, mutect2, varscan2
- CLVS2 | c.139C>T p.L47= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV51565746, COSV51567685; called by muse, mutect2, varscan2
- CNTF | c.141C>T p.N47= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV60160483; called by muse, mutect2, varscan2
- CRMP1 | c.1446C>G p.V482= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV61481488; called by muse, mutect2, varscan2
- CSMD2 | c.2460G>A p.G820= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV53932739; called by muse, mutect2, varscan2
- CXCR5 | c.159C>T p.F53= | Silent (SNP) | VAF 44/136 reads (32%) | catalogued as rs373651751; called by muse, mutect2, varscan2
- CYP2E1 | c.1461C>G p.L487= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53314316; called by muse, mutect2, varscan2
- CYYR1 | c.382T>C p.L128= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV54834792, COSV54835659; called by muse, mutect2, varscan2
- DDX55 | c.603C>T p.F201= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV53015282, COSV53016771; called by muse, mutect2, varscan2
- DMD | c.639C>T p.L213= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs779201084, COSV55862461, COSV99924838; called by muse, mutect2, varscan2
- DPH5 | c.645G>A p.E215= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV59859858; called by muse, mutect2, varscan2
- DPRX | c.435T>A p.I145= | Silent (SNP) | VAF 20/246 reads (8%) | catalogued as COSV64949786; called by muse, mutect2
- FAM174A | c.423C>T p.V141= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV57064444; called by muse, mutect2, varscan2
- FAM204A | c.117G>A p.E39= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV64987868; called by muse, mutect2
- FASTK | c.1023C>T p.F341= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as rs756967620, COSV52539086; called by muse, mutect2, varscan2
- GHR | c.1356G>A p.E452= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV50119980; called by muse, mutect2, varscan2
- GRPR | c.258C>T p.D86= | Silent (SNP) | VAF 85/103 reads (83%) | catalogued as rs1349387672, COSV66669865; called by muse, mutect2, varscan2
- GTF2H4 | c.636C>G p.L212= | Silent (SNP) | VAF 55/65 reads (85%) | catalogued as COSV52560027, COSV99462182; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2082G>A p.A694= (on ENST00000265755 / NM_016328.3; = p.A679= on NM_005685.4) | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs193094382, COSV56088939; called by muse, mutect2, varscan2
- HCRTR1 | c.816G>A p.L272= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65485883; called by muse, mutect2, varscan2
- HOXB8 | c.84C>T p.F28= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs766516844, COSV53311035; called by muse, varscan2
- HSPA9 | c.1833G>C p.L611= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV51865291; called by muse, mutect2, varscan2
- IFNK | c.306C>T p.T102= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as rs771431198, COSV51783755; called by muse, mutect2, varscan2
- INHBB | c.456C>T p.L152= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs145813735; called by muse, mutect2, varscan2
- IRAK3 | c.903G>A p.L301= | Silent (SNP) | VAF 37/64 reads (58%) | catalogued as COSV54163472; called by muse, mutect2, varscan2
- ITGAL | c.2220G>A p.P740= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs754571775, COSV63323289; called by muse, mutect2, varscan2
- ITPRID1 | c.2910T>C p.T970= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV60078201; called by muse, mutect2, varscan2
- KCNQ1 | c.1182C>A p.I394= | Silent (SNP) | VAF 85/145 reads (59%) | catalogued as COSV50118348; called by muse, mutect2, varscan2
- KSR2 | c.2175C>T p.F725= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs887069309, COSV56672676; called by muse, mutect2, varscan2
- LCN9 | c.507G>A p.P169= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs781706474, COSV52991600; called by muse, mutect2, varscan2
- MBD6 | c.2547C>G p.L849= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV63075536; called by muse, mutect2, varscan2
- MED24 | c.2244G>C p.L748= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV62419757; called by muse, varscan2
- MKI67 | c.5397G>A p.L1799= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV64075506; called by muse, mutect2, varscan2
- MUC16 | c.40305C>G p.L13435= | Silent (SNP) | VAF 41/227 reads (18%) | catalogued as COSV101110014, COSV66694562; called by muse, mutect2, varscan2
- MYH4 | c.2448C>T p.F816= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV55121884; called by muse, mutect2, varscan2
- NID1 | c.2166G>A p.G722= | Silent (SNP) | VAF 80/95 reads (84%) | catalogued as rs779547966, COSV51624369; called by muse, mutect2, varscan2
- NUP205 | c.5781G>A p.S1927= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as rs773758194, COSV53660795; called by muse, mutect2, varscan2
- OAS3 | c.984C>T p.C328= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV57447278; called by muse, mutect2, varscan2
- OAS3 | c.2793A>G p.Q931= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs1305460873, COSV57445733; called by mutect2, varscan2
- OBSCN | c.11742T>A p.S3914= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV52798028; called by muse, mutect2, varscan2
- OPN3 | c.888C>G p.L296= | Silent (SNP) | VAF 78/89 reads (88%) | catalogued as COSV59365829; called by muse, mutect2, varscan2
- OR2T33 | c.576C>T p.V192= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100531518, COSV100532223; called by muse, mutect2
- OTOP2 | c.883C>T p.L295= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV58882696; called by muse, mutect2
- PCDHB1 | c.1419A>G p.K473= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV60632003, COSV60633167; called by muse, mutect2, varscan2
- PCOLCE | c.1195C>T p.L399= | Silent (SNP) | VAF 18/140 reads (13%) | catalogued as COSV56158536; called by muse, mutect2, varscan2
- PCSK1 | c.360C>A p.L120= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV60736434; called by muse, mutect2, varscan2
- PLIN5 | c.276C>T p.L92= | Silent (SNP) | VAF 23/64 reads (36%) | catalogued as rs746004625, COSV67850500; called by muse, mutect2, varscan2
- POLR3A | c.111G>A p.V37= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs1332335491, COSV64931489; called by muse, mutect2, varscan2
- PUS7L | c.1029C>T p.I343= | Silent (SNP) | VAF 62/151 reads (41%) | catalogued as COSV61262385; called by muse, mutect2, varscan2
- PXDN | c.2832C>T p.S944= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs771987765, COSV53240111; called by muse, varscan2
- RACGAP1 | c.1788G>A p.Q596= | Silent (SNP) | VAF 47/93 reads (51%) | catalogued as COSV56700052; called by muse, mutect2, varscan2
- RADIL | c.612G>A p.R204= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV68202314; called by muse, varscan2
- RADIL | c.555G>T p.R185= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV68202318; called by muse, varscan2
- RASSF2 | c.165C>G p.L55= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV65082588; called by muse, mutect2, varscan2
- REG1A | c.42G>C p.L14= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52068767, COSV52069858, COSV52070482; called by muse, mutect2, varscan2
- RGL3 | c.1557C>T p.I519= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs375129863, COSV66506216; called by muse, mutect2, varscan2
- RIPOR1 | c.3516C>G p.L1172= (on ENST00000379312 / NM_001193522.2; = p.L1168= on NM_024519.4) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV50236027; called by muse, mutect2, varscan2
- ROBO1 | c.2850G>A p.Q950= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV71396685; called by muse, mutect2, varscan2
- SCAP | c.855C>T p.L285= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV55563495; called by muse, mutect2, varscan2
- SCG5 | c.81C>T p.Y27= | Silent (SNP) | VAF 32/108 reads (30%) | catalogued as rs1172323658, COSV55707363; called by muse, mutect2, varscan2
- SH3RF1 | c.1848C>T p.L616= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV52922722; called by muse, mutect2, varscan2
- SIGLEC12 | c.1248G>A p.G416= (on ENST00000291707 / NM_053003.4; = p.G298= on NM_033329.2) | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as rs1329274561, COSV52463137; called by muse, mutect2
- SNPH | c.756G>A p.L252= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs760887496, COSV60590082; called by muse, mutect2, varscan2
- SORCS3 | c.1173C>T p.I391= | Silent (SNP) | VAF 42/69 reads (61%) | catalogued as COSV63816699, COSV63818645; called by muse, mutect2, varscan2
- SPG11 | c.1356C>G p.L452= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs1233801047, COSV55998689, COSV56001715; called by muse, mutect2, varscan2
- SUPT20HL2 | c.975C>G p.L325= | Silent (SNP) | VAF 44/110 reads (40%) | called by muse, mutect2, varscan2
- TYK2 | c.3563G>A p.*1188= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs1302125515, COSV99315230; called by muse, mutect2, varscan2
- UBQLNL | c.270C>T p.I90= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as COSV66493988; called by muse, mutect2, varscan2
- UGT2B15 | c.1041T>G p.T347= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV57735557; called by muse, mutect2, varscan2
- ZGRF1 | c.5340G>A p.L1780= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs773373573, COSV71393121; called by muse, mutect2, varscan2
- ZNF133 | c.939C>T p.L313= (on ENST00000316358 / NM_001352454.2; = p.L312= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV60367567; called by muse, mutect2, varscan2
- ZNF257 | c.1290C>G p.P430= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV71310196; called by muse, mutect2, varscan2
- ZNF33A | c.1029C>T p.L343= (on ENST00000458705 / NM_006974.3; = p.L344= on NM_006954.2) | Silent (SNP) | VAF 89/155 reads (57%) | catalogued as COSV56726462; called by muse, mutect2, varscan2
- ZNF84 | c.1281A>G p.G427= | Silent (SNP) | VAF 37/135 reads (27%) | called by muse, mutect2, varscan2
- C16orf91 | c.*106G>A | 3'UTR (SNP) | VAF 20/36 reads (56%) | catalogued as COSV59950492; called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888429 G>C | 3'Flank (SNP) | VAF 51/107 reads (48%) | catalogued as COSV58047037; called by muse, mutect2, varscan2
- OBSCN | c.18662-2464G>T | Intron (SNP) | VAF 19/21 reads (90%) | catalogued as COSV52798049, COSV99471691; called by muse, mutect2, varscan2
- OFCC1 | n.448G>C | RNA (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- RN7SL176P | chr12:100158057 C>T | 3'Flank (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- SPHK2 | c.872+43G>C | Intron (SNP) | VAF 6/96 reads (6%) | catalogued as COSV55339468; called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 22/31 reads (71%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
